Gene-level copy-number profile of tumor specimen TCGA-G2-A2ES-01A from TCGA case TCGA-G2-A2ES, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 85.7 years (31,293 days).
Specimen TCGA-G2-A2ES-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.72d60118-f04b-4e64-8f73-ce554a70131a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G2-A2ES-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6f0b457-8a4f-4fc9-b90d-3bded194dff7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 7,928; copy number 2: 45,833; copy number 3: 4,817; copy number 4: 987; copy number 5: 28; copy number 7: 148; copy number 8: 39; copy number 10: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G2-A2ES-01A-11D-A17S-01): tumor purity 0.55, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:132,416,805–133,568,463, 14 genes (within-gene range 0–2): GPR39, YBX1P7, RN7SKP103, LYPD1, AC010974.1, NCKAP5, AC010974.2, AC016909.1, NCKAP5-AS1, AC011755.1, NCKAP5-AS2, RNU6-579P, RN7SKP154, NCKAP5-IT1.
- chr2:212,426,263–212,426,360, 1 gene: MIR548F2.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr9:9,799,423–9,803,784, 1 gene: AL513422.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 234 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:68,612,899–75,243,704, 231 genes, copy number 5–10 (broad region; genes not listed).
- chr11:75,260,127–75,265,170, 3 genes, copy number 5: AP001972.1, AP001972.5, AP001972.2.

Autosomal genes at a single copy (total copy number 1): 5,508. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
